Gene-level copy-number profile of tumor specimen TCGA-39-5034-01A from TCGA case TCGA-39-5034, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 73.1 years (26,682 days).
Specimen TCGA-39-5034-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.582b121a-b2a3-4445-8f36-480f211a1eb8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-39-5034-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 831 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5a5296c4-2dbc-4d32-b150-d9b5236ae729

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 1,892; copy number 2: 18,442; copy number 3: 26,359; copy number 4: 8,313; copy number 5: 1,480; copy number 6: 1,145; copy number 8: 233; copy number 9: 43; copy number 10: 1,688; copy number 11: 67; copy number 12: 116.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-39-5034-01A-01D-1439-01): tumor purity 0.51, ploidy 3.07, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:138,298,088–138,981,389, 14 genes (within-gene range 0–2): AC008155.1, PTMAP10, IMPDH1P3, TRIM24, RPS3AP28, SVOPL, AC013429.2, AC013429.1, AC020983.1, UQCRFS1P2, ATP6V0A4, TMEM213, KIAA1549, RNU6-1272P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,147 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:199,752,491–199,909,648, 4 genes, copy number 10: AL596266.1, AL445687.1, RNU6-778P, AL445687.2.
- chr1:203,026,498–205,134,950, 67 genes, copy number 11 (within-gene range 2–11) (broad region; genes not listed).
- chr8:38,600,661–40,520,158, 35 genes, copy number 12: RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1, AC010857.1.
- chr8:41,032,892–145,066,685, 1,615 genes, copy number 10–12 (broad region; genes not listed).
- chr19:44,228,729–46,850,846, 150 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).
- chr19:51,563,797–54,339,162, 233 genes, copy number 8 (broad region; genes not listed).
- chr19:57,065,334–57,624,724, 43 genes, copy number 9 (within-gene range 6–9): RPL7AP69, AC025588.4, USP29, ZIM3, AC025588.2, AC025588.3, DUXA, AC025588.1, ZNF264, AURKC, ZNF805, AC005261.3, ZNF460-AS1, ZNF460, AC005261.5, AC005261.1, AC005261.4, ZNF543, AC005261.2, ZNF304, ZNF547, TRAPPC2B, AC003002.1, ZNF548, AC003002.3, AC003002.2, ZNF17, ZNF749, AC004076.1, AC004076.2, VN1R1, VN1R107P, ZNF772, AC003005.2, ZNF419, AC003005.1, ZNF773, ZNF549, ZNF550, ZNF416, ZIK1, ZNF530, ZNF134.

Autosomal genes at a single copy (total copy number 1): 1,892. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
